Somatic mutation profile of tumor specimen TCGA-66-2786-01A (aliquot TCGA-66-2786-01A-01D-1522-08) from TCGA case TCGA-66-2786, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 68.6 years (25,051 days).
Specimen TCGA-66-2786-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6646f783-e806-474f-ac17-c9b851f92788.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-66-2786-11A (Solid Tissue Normal), aliquot TCGA-66-2786-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7edf9897-cfde-458e-ad0d-dc3b55b3cbd3

The open-access MAF lists 231 somatic variants for this specimen: 182 protein-altering or splice-affecting, 46 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 145, Silent 46, Nonsense Mutation 13, Splice Site 10, Frame Shift Del 9, Splice Region 2, RNA 1, Frame Shift Ins 1, 3'UTR 1, In Frame Del 1, 5'UTR 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARSB | c.943C>T p.R315* | Nonsense Mutation (SNP) | VAF 90/242 reads (37%) | catalogued as rs891298440, CM003996, COSV53728737; ClinVar: likely pathogenic; called by muse, varscan2
- CDKN2A | c.79G>T p.E27* | Nonsense Mutation (SNP) | VAF 20/62 reads (32%) | catalogued as rs1554656411, CM063892, COSV58688166; ClinVar: pathogenic; called by muse, varscan2
- TF | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs121918681, CM043106, COSV53925152; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.472C>G p.R158G | Missense Mutation (SNP) | VAF 26/70 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM004341, CM121763, COSV52677865, COSV52699654, COSV52778687; called by muse, mutect2, varscan2
- ABCC12 | c.927C>G p.I309M | Missense Mutation (SNP) | VAF 74/225 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV60919324; called by muse, mutect2, varscan2
- ABL1 | c.1357G>C p.E453Q | Missense Mutation (SNP) | VAF 32/490 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.635); catalogued as COSV59326084, COSV59334718; called by muse, mutect2
- ACSL3 | c.346G>C p.E116Q | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62485212; called by muse, mutect2, varscan2
- ADAMTS12 | c.4752G>T p.R1584S | Missense Mutation (SNP) | VAF 70/674 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100710020, COSV61283962; called by muse, mutect2, varscan2
- AGBL1 | c.2337G>T p.M779I | Missense Mutation (SNP) | VAF 56/202 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.287); catalogued as COSV66877470; called by muse, mutect2, varscan2
- ANO5 | c.1978G>T p.D660Y | Missense Mutation (SNP) | VAF 80/278 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61082265, COSV61091301; called by muse, mutect2, varscan2
- APOC3 | c.19C>G p.L7V | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.607); catalogued as COSV57139062; called by muse, mutect2, varscan2
- ATAD2 | c.4030dup p.S1344Kfs*28 | Frame Shift Ins (INS) | VAF 16/108 reads (15%) | catalogued as rs775812316; called by mutect2, varscan2
- ATP1A3 | c.2044G>A p.D682N (on ENST00000545399 / NM_001256214.2; = p.D669N on NM_152296.5) | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as COSV57491969; called by muse, mutect2, varscan2
- ATP2B3 | c.2137C>T p.R713W | Missense Mutation (SNP) | VAF 50/181 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54848929; called by muse, mutect2, varscan2
- ATRX | c.2500G>A p.A834T | Missense Mutation (SNP) | VAF 24/604 reads (4%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV64875734, COSV64885839; called by muse, mutect2
- BCAR3 | c.2397G>C p.E799D | Missense Mutation (SNP) | VAF 66/284 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV53080305; called by muse, mutect2, varscan2
- BCOR | c.461G>C p.G154A | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV60713743, COSV60721284; called by muse, mutect2, varscan2
- BCORL1 | c.4965G>T p.E1655D | Missense Mutation (SNP) | VAF 74/319 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV54409774; called by muse, mutect2, varscan2
- CADM3 | c.640G>C p.E214Q (on ENST00000368125 / NM_001127173.3; = p.E248Q on NM_021189.5) | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.589); catalogued as COSV63686422, COSV63687908; called by muse, mutect2, varscan2
- CADPS2 | c.982G>T p.G328C | Missense Mutation (SNP) | VAF 25/206 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57390367; called by muse, mutect2, varscan2
- CCNB3 | c.4072T>C p.Y1358H | Missense Mutation (SNP) | VAF 157/512 reads (31%) | SIFT tolerated (0.8); PolyPhen benign (0.066); catalogued as COSV52081180; called by muse, mutect2, varscan2
- CD200R1L | c.418C>T p.L140F | Missense Mutation (SNP) | VAF 24/352 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68005103; called by muse, mutect2
- CDH10 | c.1987G>T p.G663* | Nonsense Mutation (SNP) | VAF 56/326 reads (17%) | catalogued as COSV52578640, COSV52581433; called by muse, mutect2, varscan2
- CDH10 | c.672C>G p.N224K | Missense Mutation (SNP) | VAF 68/267 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV52602340; called by muse, mutect2, varscan2
- CDH12 | c.2005G>C p.D669H | Missense Mutation (SNP) | VAF 21/363 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66457550; called by muse, mutect2
- CHD6 | c.6409C>T p.R2137* | Nonsense Mutation (SNP) | VAF 39/129 reads (30%) | catalogued as COSV64689337; called by muse, mutect2, varscan2
- CHD8 | c.4648G>A p.D1550N (on ENST00000646647 / NM_001170629.2; = p.D1271N on NM_020920.4) | Missense Mutation (SNP) | VAF 62/189 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.694); catalogued as COSV63219535, COSV63219851; called by muse, mutect2, varscan2
- CHORDC1 | c.563+1G>T p.X188_splice | Splice Site (SNP) | VAF 62/232 reads (27%) | catalogued as COSV57707218; called by muse, mutect2, varscan2
- CHRM3 | c.1255A>G p.S419G | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99698771; called by muse, mutect2, varscan2
- CHRNB4 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs777719189, COSV55718787; called by muse, mutect2, varscan2
- CLEC9A | c.400T>A p.W134R | Missense Mutation (SNP) | VAF 26/287 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63351899; called by muse, mutect2
- CLIC2 | c.583-1G>A p.X195_splice | Splice Site (SNP) | VAF 35/151 reads (23%) | catalogued as COSV100425644; called by muse, mutect2, varscan2
- CLSTN2 | c.547G>T p.A183S | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV71725810; called by muse, mutect2
- CLSTN2 | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 22/225 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71725811; called by muse, mutect2
- CLVS2 | c.881C>G p.P294R | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.163); catalogued as COSV51570063; called by muse, mutect2, varscan2
- CMTR2 | c.683C>G p.T228S | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.023); catalogued as rs376567812; called by muse, mutect2
- CNTN6 | c.823T>C p.Y275H | Missense Mutation (SNP) | VAF 90/235 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs990536728, COSV63193421; called by muse, mutect2, varscan2
- COL22A1 | c.2647G>T p.G883* | Nonsense Mutation (SNP) | VAF 28/107 reads (26%) | catalogued as COSV57365795; called by muse, mutect2, varscan2
- COL6A6 | c.2611G>T p.E871* | Nonsense Mutation (SNP) | VAF 13/79 reads (16%) | catalogued as COSV62040375; called by muse, mutect2, varscan2
- CPS1 | c.3463G>T p.A1155S | Missense Mutation (SNP) | VAF 13/178 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51827793; called by muse, mutect2
- CSMD3 | c.5744C>T p.A1915V (on ENST00000297405 / NM_001363185.1; = p.A1811V on NM_052900.3) | Missense Mutation (SNP) | VAF 14/207 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as rs553075730, COSV52350462; called by muse, mutect2
- CSTF2 | c.1045C>A p.P349T | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.55); catalogued as COSV65895407; called by muse, mutect2, varscan2
- CTAGE1 | c.393A>C p.E131D | Missense Mutation (SNP) | VAF 12/362 reads (3%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.72); catalogued as COSV66943234, COSV66945393; called by muse, mutect2
- CX3CR1 | c.841G>T p.V281F | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV64195665; called by muse, mutect2, varscan2
- DARS2 | c.493-2A>G p.X165_splice | Splice Site (SNP) | VAF 6/24 reads (25%) | catalogued as rs929742493, COSV53409758; called by muse, mutect2, varscan2
- DCAF12L2 | c.380C>T p.S127L | Missense Mutation (SNP) | VAF 50/196 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.255); catalogued as COSV63584639; called by muse, mutect2, varscan2
- DGKB | c.2024G>T p.G675V | Missense Mutation (SNP) | VAF 60/211 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51826779; called by muse, mutect2, varscan2
- DST | c.5620T>C p.S1874P | Missense Mutation (SNP) | VAF 64/256 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV99757871; called by muse, mutect2, varscan2
- DUS2 | c.1312G>C p.E438Q | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.131); catalogued as COSV62710166; called by muse, mutect2, varscan2
- EIF3A | c.2903C>G p.P968R | Missense Mutation (SNP) | VAF 9/249 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV64963876; called by muse, mutect2
- EIF4B | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.75); PolyPhen benign (0.366); catalogued as rs367932879; called by muse, mutect2, varscan2
- EMSY | c.3331C>T p.R1111C | Missense Mutation (SNP) | VAF 20/201 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.165); catalogued as rs774697937, COSV58259784; called by muse, mutect2, varscan2
- ENTHD1 | c.1709T>C p.I570T | Missense Mutation (SNP) | VAF 41/179 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs1204556425, COSV57326263; called by muse, mutect2, varscan2
- EPHX4 | c.494T>C p.L165P | Missense Mutation (SNP) | VAF 28/360 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64890202; called by muse, mutect2
- EXD2 | c.1333A>T p.I445F (on ENST00000312994 / NM_001193362.1; = p.I320F on NM_018199.3) | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.582); catalogued as COSV57282790; called by muse, mutect2, varscan2
- EZHIP | c.40C>T p.Q14* | Nonsense Mutation (SNP) | VAF 11/53 reads (21%) | catalogued as COSV57955886; called by muse, mutect2, varscan2
- FAM160B2 | c.2207C>A p.S736Y | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV57161043; called by muse, mutect2, varscan2
- FAM209A | c.301A>T p.K101* | Nonsense Mutation (SNP) | VAF 78/317 reads (25%) | catalogued as COSV54769575; called by muse, mutect2, varscan2
- FARP2 | c.2788-1G>A p.X930_splice | Splice Site (SNP) | VAF 16/148 reads (11%) | catalogued as COSV50885809; called by muse, mutect2
- FAT4 | c.14792A>G p.N4931S | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV58713956; called by muse, mutect2, varscan2
- FBXL2 | c.78C>G p.F26L | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); catalogued as COSV52143682; called by muse, mutect2, varscan2
- FBXO4 | c.382A>G p.I128V | Missense Mutation (SNP) | VAF 126/460 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs369814713; called by muse, mutect2, varscan2
- FMR1 | c.1361G>C p.R454P | Missense Mutation (SNP) | VAF 78/350 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV54426577, COSV54428337; called by muse, mutect2, varscan2
- GALK2 | c.100C>A p.P34T | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59106249; called by muse, mutect2, varscan2
- GCM1 | c.1267C>A p.H423N | Missense Mutation (SNP) | VAF 126/830 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV52521497, COSV52523211; called by muse, varscan2
- GDAP1 | c.625C>G p.L209V | Missense Mutation (SNP) | VAF 30/274 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55187639, COSV99619246; called by muse, mutect2, varscan2
- GGT5 | c.1750G>T p.A584S | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.387); catalogued as COSV54070722, COSV54073048; called by muse, mutect2, varscan2
- GOLGA3 | c.215C>T p.T72M | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.006); catalogued as rs763136916, COSV52645512, COSV52646595; called by muse, mutect2, varscan2
- GPRIN3 | c.1069C>A p.Q357K | Missense Mutation (SNP) | VAF 55/120 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.151); catalogued as COSV60886775; called by muse, mutect2, varscan2
- GSE1 | c.1847G>A p.R616H | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs367594478; called by muse, mutect2, varscan2
- GYG2 | c.505G>T p.V169L | Missense Mutation (SNP) | VAF 62/198 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58552115; called by muse, mutect2, varscan2
- HAS1 | c.637G>C p.G213R | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV55790297; called by muse, mutect2, varscan2
- HLTF | c.2173G>T p.A725S | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.02); catalogued as COSV59504221; called by muse, mutect2, varscan2
- HOOK2 | c.748G>T p.E250* | Nonsense Mutation (SNP) | VAF 11/25 reads (44%) | catalogued as COSV53404619; called by muse, mutect2, varscan2
- HOXC10 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 46/282 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV57727314; called by muse, mutect2, varscan2
- HS3ST4 | c.857T>C p.V286A | Missense Mutation (SNP) | VAF 40/170 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779140172, COSV58812234; called by muse, mutect2, varscan2
- HSPG2 | c.3676C>G p.L1226V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV65978537; called by muse, mutect2
- IGHM | c.1240G>A p.V414M | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as rs781884098; called by muse, mutect2, varscan2
- KANSL2 | c.221A>G p.N74S | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs554290180, COSV63480658; called by muse, mutect2, varscan2
- KNG1 | c.791G>T p.C264F | Missense Mutation (SNP) | VAF 52/225 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53981748; called by muse, mutect2, varscan2
- LTV1 | c.57C>G p.H19Q | Missense Mutation (SNP) | VAF 28/337 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.779); catalogued as COSV62536434, COSV62536832; called by muse, mutect2
- LUZP1 | c.991A>C p.N331H | Missense Mutation (SNP) | VAF 40/327 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV56506286; called by muse, mutect2, varscan2
- MAGEB10 | c.554A>G p.D185G | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV63313020; called by muse, mutect2
- MEIS1 | c.482A>C p.K161T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV55493637; called by muse, mutect2
- MEP1B | c.2096A>G p.H699R | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.011); catalogued as rs900475374, COSV52500612; called by muse, mutect2, varscan2
- MFN1 | c.835C>A p.R279S | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54943199; called by muse, mutect2, varscan2
- MIA2 | c.940A>T p.K314* | Nonsense Mutation (SNP) | VAF 58/156 reads (37%) | catalogued as COSV54503162; called by muse, mutect2, varscan2
- MPDZ | c.4082G>T p.G1361V | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1225982249, COSV59926145; called by muse, mutect2, varscan2
- MYF5 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 8/127 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV57354247; called by muse, mutect2
- MYO10 | c.1911C>G p.I637M | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV72563880; called by muse, mutect2, varscan2
- NDUFS6 | c.362A>G p.Q121R | Missense Mutation (SNP) | VAF 38/374 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.282); catalogued as COSV56877953; called by muse, mutect2
- NEDD4 | c.2403+1G>A p.X801_splice (on ENST00000508342 / NM_001284338.1; = p.X382_splice on NM_006154.4) | Splice Site (SNP) | VAF 41/179 reads (23%) | catalogued as COSV59067710; called by muse, mutect2, varscan2
- NELL1 | c.677-2A>T p.X226_splice | Splice Site (SNP) | VAF 25/111 reads (23%) | catalogued as COSV54338352; called by muse, mutect2, varscan2
- NETO1 | c.1365G>T p.L455F | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT tolerated, low confidence (0.71); PolyPhen probably damaging (0.991); catalogued as COSV55016993; called by muse, mutect2, varscan2
- NLGN3 | c.2399C>A p.P800Q (on ENST00000358741 / NM_181303.2; = p.P780Q on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV62445628; called by muse, mutect2, varscan2
- NTRK3 | c.888T>G p.S296R | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.655); catalogued as COSV58149036; called by muse, mutect2, varscan2
- OR2A12 | c.404T>A p.M135K | Missense Mutation (SNP) | VAF 14/374 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV68822162; called by muse, mutect2
- OR2M7 | c.841G>A p.V281I | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs143090101, COSV58740084; called by muse, mutect2, varscan2
- OR4C46 | c.649G>A p.V217M | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.292); catalogued as COSV100060364, COSV60221609; called by muse, mutect2, varscan2
- OR5R1 | c.77del p.P26Rfs*7 | Frame Shift Del (DEL) | VAF 49/256 reads (19%) | catalogued as rs1565136350; called by mutect2, pindel, varscan2
- OTUD6A | c.867G>T p.*289Yext*5 | Nonstop Mutation (SNP) | VAF 8/22 reads (36%) | catalogued as COSV57974633; called by muse, mutect2, varscan2
- PDZD4 | c.852C>A p.D284E | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV51251625, COSV51252963; called by muse, mutect2
- PEG3 | c.1568A>T p.H523L | Missense Mutation (SNP) | VAF 28/346 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55651638; called by muse, mutect2
- PER1 | c.3224C>G p.S1075C | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57922677; called by muse, mutect2, varscan2
- PER1 | c.1088G>C p.R363P | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV57922686; called by muse, mutect2, varscan2
- PIWIL1 | c.1322G>A p.W441* | Nonsense Mutation (SNP) | VAF 39/486 reads (8%) | catalogued as rs1451658538, COSV55353107; called by muse, mutect2
- PKP4 | c.3458C>G p.S1153C | Missense Mutation (SNP) | VAF 30/342 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as COSV61580851; called by muse, mutect2
- PNCK | c.492G>T p.Q164H (on ENST00000340888 / NM_001366975.1; = p.Q247H on NM_001039582.3) | Missense Mutation (SNP) | VAF 77/296 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV61745854; called by muse, mutect2, varscan2
- PPFIA2 | c.2786C>T p.A929V | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV61060273; called by muse, mutect2, varscan2
- PPFIBP2 | c.2001C>T p.N667= | Splice Region (SNP) | VAF 113/426 reads (27%) | catalogued as rs755779633, COSV55083752; called by muse, mutect2
- PPP2R3A | c.2342A>T p.Q781L | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as COSV53872265; called by muse, mutect2, varscan2
- PRB4 | c.658C>A p.P220T | Missense Mutation (SNP) | VAF 97/338 reads (29%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.763); catalogued as rs574597591, COSV54400818; called by muse, mutect2, varscan2
- PRB4 | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 184/721 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.055); catalogued as COSV54400833; called by muse, mutect2, varscan2
- PRKD2 | c.1779C>A p.S593R | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.991); catalogued as COSV52190510; called by muse, mutect2, varscan2
- PRKG1 | c.1315C>A p.L439M | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.775); catalogued as COSV64779807; called by muse, mutect2, varscan2
- PRRG3 | c.505G>C p.V169L | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV64851640; called by muse, mutect2, varscan2
- PTPRT | c.3814G>T p.V1272L | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.304); catalogued as COSV100628535; called by mutect2, varscan2
- RALGAPB | c.2563-1G>C p.X855_splice | Splice Site (SNP) | VAF 46/195 reads (24%) | catalogued as COSV53445852; called by muse, mutect2, varscan2
- REM1 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.065); catalogued as COSV52430533; called by muse, mutect2, varscan2
- RNF144A | c.179A>T p.E60V | Missense Mutation (SNP) | VAF 62/201 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0.261); catalogued as COSV57985991; called by muse, mutect2, varscan2
- RUFY1 | c.899G>C p.R300T | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as rs776973223, COSV60164364; called by muse, mutect2, varscan2
- RYR2 | c.243G>T p.M81I | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV63721094; called by muse, mutect2, varscan2
- RYR3 | c.9011T>C p.F3004S (on ENST00000389232; = p.F3005S on NM_001036.6) | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV66811646; called by muse, mutect2, varscan2
- SCAP | c.3627C>G p.I1209M | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as COSV55549457; called by muse, mutect2, varscan2
- SCN3A | c.3194G>C p.R1065T | Missense Mutation (SNP) | VAF 21/212 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as COSV51827923; called by muse, mutect2
- SENP2 | c.340A>G p.N114D | Missense Mutation (SNP) | VAF 43/212 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV56198768; called by muse, mutect2, varscan2
- SETD2 | c.5266G>T p.E1756* | Nonsense Mutation (SNP) | VAF 72/182 reads (40%) | catalogued as COSV57447230, COSV57455108; called by muse, mutect2, varscan2
- SH3RF1 | c.1738C>A p.Q580K | Missense Mutation (SNP) | VAF 73/201 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV52926211; called by muse, mutect2, varscan2
- SHPRH | c.4594C>G p.L1532V (on ENST00000275233 / NM_001042683.3; = p.L1536V on NM_173082.3) | Missense Mutation (SNP) | VAF 44/580 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1420032880, COSV51619605; called by muse, mutect2
- SIGLEC1 | c.3356A>G p.Y1119C | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52475249; called by muse, mutect2, varscan2
- SIK2 | c.436G>C p.E146Q | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59256812; called by muse, mutect2, varscan2
- SLC18A1 | c.623C>G p.S208C | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV52351749; called by muse, mutect2, varscan2
- SLC22A8 | c.1397C>A p.T466K | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.929); catalogued as COSV100267680, COSV60327617; called by muse, mutect2
- SLC26A8 | c.943-1G>C p.X315_splice | Splice Site (SNP) | VAF 63/136 reads (46%) | catalogued as COSV62887411, COSV62888125; called by muse, mutect2, varscan2
- SLC6A18 | c.1036T>C p.Y346H | Missense Mutation (SNP) | VAF 34/240 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57255138; called by muse, mutect2, varscan2
- SLITRK4 | c.835C>T p.Q279* | Nonsense Mutation (SNP) | VAF 94/310 reads (30%) | catalogued as COSV62026672; called by muse, varscan2
- SMCR8 | c.552G>C p.K184N | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58181729; called by muse, mutect2
- STARD8 | c.54G>T p.K18N | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV52934135; called by muse, mutect2, varscan2
- STK11IP | c.1094C>T p.S365L | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.465); catalogued as COSV55257130; called by muse, mutect2, varscan2
- SYNE1 | c.19366G>T p.D6456Y (on ENST00000367255 / NM_182961.4; = p.D6385Y on NM_033071.3) | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV55131300; called by muse, mutect2, varscan2
- SYNE1 | c.19365A>T p.E6455D (on ENST00000367255 / NM_182961.4; = p.E6384D on NM_033071.3) | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.963); catalogued as COSV55131353; called by muse, mutect2, varscan2
- TBC1D25 | c.944A>G p.H315R | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV65124896; called by muse, mutect2, varscan2
- TECTA | c.4418G>A p.R1473H | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV50837882; called by muse, varscan2
- TFCP2L1 | c.217C>G p.Q73E | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.58); catalogued as COSV55295938; called by muse, mutect2, varscan2
- TICRR | c.2524G>A p.D842N | Missense Mutation (SNP) | VAF 55/158 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.415); catalogued as COSV51548444; called by muse, mutect2, varscan2
- TMEM132B | c.1592T>C p.I531T | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV54774431; called by muse, mutect2, varscan2
- TMEM161A | c.1037A>T p.E346V | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV50778337; called by muse, mutect2, varscan2
- TMX3 | c.390T>C p.S130= | Splice Region (SNP) | VAF 28/286 reads (10%) | catalogued as COSV55188551; called by muse, mutect2
- TNN | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as rs773607661, COSV53421649; called by muse, mutect2, varscan2
- TNS3 | c.1223G>T p.R408L | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.07); catalogued as COSV60801269; called by muse, mutect2, varscan2
- TPM1 | c.593A>G p.K198R | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0.01); catalogued as COSV51268307; called by muse, mutect2
- TRIM46 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs866560615, COSV55279009, COSV55280426; called by muse, mutect2, varscan2
- TRPV5 | c.1817G>A p.R606Q | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143560130; called by muse, mutect2, varscan2
- TTN | c.89415G>C p.E29805D (on ENST00000591111; = p.E22381D on NM_003319.4) | Missense Mutation (SNP) | VAF 120/418 reads (29%) | PolyPhen probably damaging (0.99); catalogued as COSV60417495; called by muse, mutect2, varscan2
- TTN | c.59792T>C p.I19931T (on ENST00000591111; = p.I12507T on NM_003319.4) | Missense Mutation (SNP) | VAF 49/199 reads (25%) | PolyPhen benign (0.215); catalogued as rs765749707, COSV60243457; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.38644G>A p.D12882N (on ENST00000591111; = p.D5458N on NM_003319.4) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | PolyPhen possibly damaging (0.691); catalogued as COSV60417587; called by muse, mutect2, varscan2
- TTN | c.11408A>G p.Q3803R (on ENST00000591111; = p.Q3757R on NM_003319.4) | Missense Mutation (SNP) | VAF 80/280 reads (29%) | catalogued as COSV60417632; called by muse, mutect2, varscan2
- TUT7 | c.1524C>G p.I508M | Missense Mutation (SNP) | VAF 114/425 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as COSV52899734; called by muse, mutect2, varscan2
- TYRO3 | c.268T>C p.Y90H | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.74); catalogued as COSV55487936; called by muse, mutect2
- TYW3 | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs1172771294, COSV100904852, COSV63802869, COSV63803459; called by muse, mutect2, varscan2
- WDR3 | c.1477G>T p.D493Y | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); catalogued as COSV62525796; called by muse, mutect2, varscan2
- WDR7 | c.1975G>C p.E659Q | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.177); catalogued as COSV54365849; called by muse, mutect2
- WDR72 | c.430T>A p.L144M | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64755063; called by muse, mutect2, varscan2
- WSCD2 | c.1669G>C p.G557R | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV54592553, COSV99775068; called by muse, mutect2, varscan2
- ZBTB7A | c.1208C>A p.T403N | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV59329591; called by muse, mutect2, varscan2
- ZDHHC5 | c.2122G>A p.G708S | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54709580, COSV54709754; called by muse, mutect2, varscan2
- ZNF407 | c.2606T>G p.I869S | Missense Mutation (SNP) | VAF 42/169 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55274653; called by muse, mutect2, varscan2
- ZNF569 | c.1853G>A p.S618N | Missense Mutation (SNP) | VAF 94/330 reads (28%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.878); catalogued as COSV57599994; called by muse, mutect2, varscan2
- ZNF586 | c.809C>T p.S270L | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.67); PolyPhen benign (0.31); catalogued as rs946422174, COSV66972466, COSV66972813; called by muse, mutect2, varscan2
- ABI3BP | c.548del p.N183Tfs*2 | Frame Shift Del (DEL) | VAF 25/126 reads (20%) | called by mutect2, pindel, varscan2
- COLEC12 | c.1654_1666del p.T552Lfs*90 | Frame Shift Del (DEL) | VAF 5/9 reads (56%) | called by mutect2, varscan2
- GPR152 | c.1133_1180del p.P378_N393del | In Frame Del (DEL) | VAF 11/65 reads (17%) | called by muse*, mutect2
- MAGEB6B | c.1159T>C p.Y387H | Missense Mutation (SNP) | VAF 81/314 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.047); called by muse, varscan2
- METAP2 | c.1005del p.Q335Hfs*13 | Frame Shift Del (DEL) | VAF 18/77 reads (23%) | called by mutect2, pindel, varscan2
- PDS5A | c.3139del p.H1047Mfs*4 | Frame Shift Del (DEL) | VAF 26/76 reads (34%) | called by mutect2, pindel, varscan2
- POLR2A | c.3304A>G p.M1102V | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- PRUNE2 | c.8558-7_8569del p.X2853_splice | Splice Site (DEL) | VAF 6/48 reads (13%) | called by mutect2, pindel
- SAFB2 | c.1321_1324del p.N441Pfs*36 | Frame Shift Del (DEL) | VAF 20/70 reads (29%) | called by pindel, varscan2
- SPATA31A1 | c.368del p.P123Qfs*30 | Frame Shift Del (DEL) | VAF 74/185 reads (40%) | called by mutect2, pindel, varscan2
- VPS13C | c.1516_1519del p.D506Nfs*15 (on ENST00000644861 / NM_020821.3; = p.D463Nfs*15 on NM_017684.5) | Frame Shift Del (DEL) | VAF 47/191 reads (25%) | called by mutect2, pindel, varscan2
- XRCC1 | c.1712+2T>A p.X571_splice | Splice Site (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- ZNF516 | c.1703_1707del p.P568Qfs*10 | Frame Shift Del (DEL) | VAF 11/30 reads (37%) | called by pindel, varscan2
- ABCC10 | c.2340C>G p.L780= (on ENST00000372530 / NM_001198934.2; = p.L752= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as COSV55095218; called by muse, mutect2, varscan2
- ADGRG2 | c.1167C>A p.S389= (on ENST00000379869 / NM_001079858.3; = p.S386= on NM_005756.4) | Silent (SNP) | VAF 100/383 reads (26%) | catalogued as COSV61341962; called by muse, mutect2, varscan2
- ANKS1B | c.3564A>T p.L1188= (on ENST00000547776 / NM_152788.4; = p.L354= on NM_020140.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 67/263 reads (25%) | catalogued as COSV59126206; called by muse, mutect2, varscan2
- ANO5 | c.213C>A p.I71= | Silent (SNP) | VAF 26/117 reads (22%) | catalogued as COSV61091291; called by muse, mutect2, varscan2
- ATP2B3 | c.1989C>T p.N663= | Silent (SNP) | VAF 26/177 reads (15%) | catalogued as rs200802886, COSV54864791; called by muse, mutect2, varscan2
- BBX | c.1455C>T p.S485= | Silent (SNP) | VAF 16/207 reads (8%) | catalogued as rs200479657; called by muse, mutect2
- BDP1 | c.6753A>G p.P2251= | Silent (SNP) | VAF 26/264 reads (10%) | catalogued as COSV62435865; called by muse, mutect2
- C10orf71 | c.732C>T p.T244= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs368739800; called by muse, mutect2, varscan2
- CDT1 | c.33G>T p.A11= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV99967289; called by muse, mutect2, varscan2
- CEACAM21 | c.165G>A p.V55= | Silent (SNP) | VAF 31/105 reads (30%) | catalogued as COSV51814977, COSV99494891; called by muse, mutect2, varscan2
- COL9A1 | c.759T>C p.H253= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs1264012472, COSV57895401; called by muse, mutect2, varscan2
- CPS1 | c.4443C>T p.R1481= | Silent (SNP) | VAF 144/588 reads (24%) | catalogued as COSV51827810; called by muse, varscan2
- CTCF | c.1689A>G p.T563= | Silent (SNP) | VAF 86/300 reads (29%) | catalogued as rs1434608955, COSV50469536, COSV50540839; called by muse, mutect2, varscan2
- CTNNA2 | c.183T>G p.A61= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as COSV63609377; called by muse, mutect2, varscan2
- DVL3 | c.1584G>A p.G528= | Silent (SNP) | VAF 26/114 reads (23%) | catalogued as COSV53048095; called by mutect2, varscan2
- IDO2 | c.405G>T p.L135= (on ENST00000389060; = p.L148= on NM_194294.2) | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV58430586; called by muse, mutect2, varscan2
- KIAA0408 | c.303G>C p.L101= | Silent (SNP) | VAF 48/380 reads (13%) | catalogued as COSV100846977; called by muse, mutect2, varscan2
- KIZ | c.1185G>A p.Q395= | Silent (SNP) | VAF 21/80 reads (26%) | catalogued as COSV55689109; called by muse, mutect2, varscan2
- KRT8 | c.219G>A p.L73= | Silent (SNP) | VAF 12/110 reads (11%) | catalogued as rs1036555640, COSV53179666; called by muse, mutect2
- LDHAL6B | c.438T>A p.G146= | Silent (SNP) | VAF 97/329 reads (29%) | catalogued as COSV55697626; called by muse, mutect2, varscan2
- LRP2 | c.2982C>T p.F994= | Silent (SNP) | VAF 32/105 reads (30%) | catalogued as COSV55579540; called by muse, mutect2, varscan2
- MAP1A | c.8388C>T p.F2796= | Silent (SNP) | VAF 13/186 reads (7%) | catalogued as rs764532855, COSV55814055; called by muse, mutect2
- MYO6 | c.2043A>G p.E681= | Silent (SNP) | VAF 12/178 reads (7%) | catalogued as COSV64122114; called by muse, mutect2
- NCBP3 | c.1515T>C p.F505= | Silent (SNP) | VAF 47/120 reads (39%) | catalogued as COSV50112827; called by muse, mutect2, varscan2
- NCOA1 | c.1458C>T p.F486= | Silent (SNP) | VAF 49/173 reads (28%) | catalogued as COSV56054837; called by muse, mutect2, varscan2
- NCOA4 | c.519A>T p.A173= | Silent (SNP) | VAF 42/146 reads (29%) | called by muse, mutect2, varscan2
- NHS | c.4419C>A p.P1473= | Silent (SNP) | VAF 79/344 reads (23%) | catalogued as COSV66284770; called by muse, mutect2, varscan2
- NKX2-2 | c.186G>A p.K62= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV65820545; called by muse, mutect2, varscan2
- NRXN1 | c.1923G>T p.V641= | Silent (SNP) | VAF 50/341 reads (15%) | catalogued as COSV58434250, COSV58502302; called by muse, varscan2
- ONECUT1 | c.559C>T p.L187= | Silent (SNP) | VAF 29/118 reads (25%) | catalogued as COSV59951367; called by muse, mutect2, varscan2
- PLEC | c.10692G>C p.L3564= (on ENST00000322810 / NM_201380.4; = p.L3454= on NM_000445.5) | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as COSV59706720; called by muse, mutect2
- PLPPR4 | c.2028G>C p.L676= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV64568009; called by muse, mutect2, varscan2
- PROKR2 | c.816G>A p.K272= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as rs367826294, COSV99027846; called by muse, mutect2, varscan2
- QRFPR | c.144C>G p.L48= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV57676351, COSV57680864; called by muse, mutect2
- RASL11B | c.42C>G p.P14= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV50535165, COSV50535931; called by muse, mutect2, varscan2
- RYR2 | c.8094A>G p.E2698= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as COSV63721101; called by muse, mutect2, varscan2
- SEMA5B | c.3183C>T p.H1061= | Silent (SNP) | VAF 32/120 reads (27%) | catalogued as COSV52110923; called by muse, mutect2, varscan2
- SIGLEC7 | c.591C>A p.T197= | Silent (SNP) | VAF 24/174 reads (14%) | catalogued as COSV58318385, COSV99978469; called by muse, mutect2, varscan2
- SLC39A10 | c.1062C>T p.P354= | Silent (SNP) | VAF 50/265 reads (19%) | catalogued as COSV62770120; called by muse, mutect2, varscan2
- SLCO1C1 | c.1617A>G p.G539= | Silent (SNP) | VAF 74/267 reads (28%) | catalogued as COSV56881869; called by muse, mutect2, varscan2
- SLITRK3 | c.2901C>G p.L967= | Silent (SNP) | VAF 100/496 reads (20%) | catalogued as COSV53851275, COSV53854620, COSV99580203; called by muse, mutect2, varscan2
- SMARCC2 | c.2370C>G p.T790= | Silent (SNP) | VAF 52/187 reads (28%) | catalogued as COSV57226213; called by muse, mutect2, varscan2
- STAB2 | c.2883C>A p.T961= | Silent (SNP) | VAF 34/153 reads (22%) | catalogued as COSV101185667, COSV66335582, COSV66345583; called by muse, mutect2, varscan2
- USP9X | c.5955A>T p.S1985= | Silent (SNP) | VAF 94/283 reads (33%) | catalogued as COSV61076759; called by muse, mutect2, varscan2
- VPS50 | c.2763C>T p.I921= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as COSV59923944; called by muse, mutect2, varscan2
- ZNF354C | c.13C>T p.L5= | Silent (SNP) | VAF 27/199 reads (14%) | catalogued as rs149113509; called by muse, mutect2, varscan2
- CXCL12 | c.*1966T>C | 3'UTR (SNP) | VAF 5/14 reads (36%) | catalogued as COSV100985927; called by muse, mutect2, varscan2
- MORF4 | n.956T>A | RNA (SNP) | VAF 63/126 reads (50%) | called by muse, mutect2, varscan2
- ZNF493 | c.-112T>A | 5'UTR (SNP) | VAF 46/138 reads (33%) | catalogued as COSV100828770; called by muse, mutect2, varscan2
